TCGA case TCGA-FZ-5922 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a46fb053-616d-41e4-b38b-2bccf17125c0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 81 years; Vital status: Dead; Days to death: 1,101 days (3.0 years); Cause of death: Cancer Related; Cause of death source: Death Certificate.

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 81.1 years (29,633 days); Year of diagnosis: 2007; Method of diagnosis: Cytology; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,101 days (3.0 years); Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 5; Tumor largest dimension diameter: 1.8 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib Hydrochloride; Days to treatment start: 76 days; Days to treatment end: 442 days (1.2 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Days to treatment start: 639 days (1.7 years); Days to treatment end: 800 days (2.2 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Peritoneum, NOS. Age at diagnosis: 83.2 years (30,373 days); Days to diagnosis: 740 days (2.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
3. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Peritoneum, NOS. Age at diagnosis: 83.2 years (30,376 days); Days to diagnosis: 743 days (2.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 740 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 740 days (2.0 years).
- Day 743 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Peritoneum, NOS; Days to recurrence: 743 days (2.0 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,101 days (3.0 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FZ-5922-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 2; Shortest dimension: 0.2.
  Slide TCGA-FZ-5922-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50.
  Slide TCGA-FZ-5922-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50.
- Sample TCGA-FZ-5922-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FZ-5922-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.9; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymph nodes examined: Yes; Tumor status: With tumor; Cause of death: Pancreatic Cancer; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 1: Pharmaceutical therapy drug name: Gemzar; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: Tarceva; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,101 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,101 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 740 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FZ-5922-01A-11D-1608-01): tumor purity 0.38, ploidy 1.88, whole-genome doublings 0.
